Surgical pathology report (de-identified scan), TCGA case TCGA-CV-A6JE, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-A6JE-01A (Primary Tumor).

[page 1 of 3]
M

(159.0cm 60.4kg BSA: 1.63m²)

Accession:

Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) LEFT NECK DISSECTION, LEVEL 1:

Ten lymph nodes, negative for tumor (0/10)
Salivary gland, negative for tumor

(B) LEFT NECK DISSECTION, LEVEL 2A:

Eighteen lymph nodes, negative for tumor (0/18)

(C) LEFT NECK DISSECTION, LEVEL 3:

Six lymph nodes, negative for tumor (0/6)

(D) COMPOSITE RESECTION, LEFT PARTIAL MAXILLA TUBEROSITY, LEFT PARTIAL GLOSSECTOMY, LEFT SEGMENTAL MANDIBULECTOMY, LEFT PARTIAL PHARYNGECTOMY:

INVASIVE SQUAMOUS CARCINOMA -- Moderately differentiated

Tumor Features:

Gross: Ulcerating

Size: 3.2 cm in largest dimension

Invasion: Present, depth 0.8 cm

Tumor Border: infiltrative with thick cords > 4 cells

Perineural Invasion: Absent

Vascular Invasion: Absent

Bone / Cartilage Invasion: Pending Decalcification (see addendum)

(E) MEDIAL PTERYGOID PLATE:

Skeletal muscle and fragment of bone, negative for tumor

(F) LATERAL BUCCAL MUCOSAL MARGIN

Squamous mucosa, negative for tumor

(G) POSTERIOR ALVEOLAR MUCOSAL MARGIN:

Squamous mucosa, negative for tumor

(H) SOFT PALATE MUCOSAL MARGIN:

Squamous mucosa, negative for tumor

(I) LEFT MAXILLARY GINGIVA:

Squamous mucosa, negative for tumor

GROSS DESCRIPTION

(A) LEFT NECK DISSECTION, LEVEL 1 - A 6.0 x 4.2 x 1.7 cm aggregate of fibroadipose tissue. The tissue is dissected to reveal six possible lymph nodes ranging from 0.5 x 0.2 x 0.2 cm - 1.5 x 0.9 x 0.4 cm, and a 4.7 x 3.0 x 1.5 cm gland. Cut surfaces of the gland are tan, lobulated, and unremarkable.

SECTION CODE: A1, A2, two possible lymph nodes in each; A3, one possible lymph node serially sectioned; A4, one possible lymph node, serially sectioned; A5, representative section of gland.

(B) LEFT NECK DISSECTION, LEVEL 2A - A 7.2 x 3.5 x 0.8 cm aggregate of fibroadipose tissue. The tissue is dissected to reveal eighteen possible lymph nodes, ranging from (0.2 x 0.2 x 0.2 cm - 1.1 x 0.9 x 0.7 cm).

SECTION CODE: B1, three possible lymph nodes; B2, four possible lymph nodes; B3-B5, three possible lymph nodes in

100-0-3
Carcinoma, squamous cell
NOS 807013
Site: Oral cavity C06.9
Jt 8/9/13

[page 2 of 3]
M

(159.0cm 60.4kg BSA: 1.63m²)

Accession:

Specimen Date/Time:

each; B6, one possible lymph node, serially sectioned; B7, one possible lymph node, serially sectioned.

(C) LEFT NECK DISSECTION, LEVEL 3 – A (2.8 x 2.7 x 0.6 cm) aggregate of fibroadipose tissue. The tissue is dissected to reveal five possible lymph nodes, ranging from (0.3 x 0.3 x 0.2 cm – 0.7 x 0.5 x 0.3 cm).

SECTION CODE: C1, C2, two possible lymph nodes in each; C3, one possible lymph node bisected.

(D) COMPOSITE RESECTION LEFT PARTIAL MAXILLA TUBEROSITY, LEFT PARTIAL GLOSSECTOMY, LEFT SEGMENTAL MANDIBULECTOMY, LEFT PARTIAL PHARYNGECTOMY – A composite section consisting of a segment of mandible with angle and condyles, posterior portion of pharynx, posterior maxillary tuberosity and medial portion of tongue with underlying skeletal muscle. The specimen measures 8 cm from anterior to posterior, 4.9 cm from lateral to medial and 4.6 cm from superior to inferior. The mucosal surface shows an ulcerated area (3.2 x 2.4 cm) which is located 0.4 cm from the lateral buccal margin, 0.7 cm from the medial tongue margin, 1.3 cm from the anterior soft tissue margin, and 1.7 cm from the posterior pharyngeal margin. Cut surfaces show gray-white firm tissue underlying the ulcerated area, extending to a depth of 0.8 cm. The bone underlying this ulcerated area shows fine pitting and deformity. Representative sections are submitted. The bone is submitted to the bone lab following decalcification and further sectioning.

SECTION CODE: D1, anterior soft tissue; D2-D9, representative serial sections from anterior to posterior including ulcer (D3-D4, D5-D6, D7-D8, one cross section each); D10, posterior pharyngeal soft tissue. D11, anterior margin; D12, D13, pitted bone underlying ulcerated area; D11-D13, submitted for decalcification.

(E) MEDIAL PTERYGOID PLATE – A portion of bone with attached fibromuscular tissue (2.2 x 1.7 x 1 cm). Cut surfaces of the soft tissue are unremarkable. The soft tissue is submitted in E1 and the bone is submitted to the bone lab for decalcification and further sectioning. Representative section of the pterygoid plate submitted in E2 for decalcification.

(F) LATERAL BUCCAL MUCOSAL MARGIN – A single strip of mucosa (3 x 0.5 x 0.2 cm). The specimen is submitted entirely for frozen section diagnosis in F.

*FS/DX: NO TUMOR PRESENT.

(G) POSTERIOR ALVEOLAR MUCOSAL MARGIN – A single inked strip of soft tissue (2.5 x 0.4 x 0.4 cm). The specimen is submitted entirely ink side down for frozen section diagnosis in G.

*FS/DX: NO TUMOR PRESENT.

(H) SOFT PALATE MUCOSAL MARGIN – A single strip of mucosa (3.4 x 0.4 x 0.4 cm). The specimen is bisected and submitted entirely for frozen section diagnosis in H.

*FS/DX: NO TUMOR PRESENT.

(I) LEFT MAXILLARY GINGIVA – A single mucosa covered soft tissue (1 x 0.6 x 0.4 cm). The specimen is bisected and submitted entirely for frozen section diagnosis in I.

*FS/DX: NO TUMOR PRESENT.

CLINICAL HISTORY

SNOMED CODES

T-11180, T-11170, T-55000, T-53000, M-80703, M-43000, "Some tests reported here may have been developed and performance characteristics determined by These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by:

Start of ADDENDUM

[page 3 of 3]
Accession: M (109.0cm 60.4kg BSA: 1.63m²)
Specimen Date/Time:

ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

COMMENT

Additional bone sections from part (D) of the mandible are negative for bone invasion. The anterior mandibular margin is also negative for carcinoma.

Bone section from part (E) medial pterygoid plate is negative for carcinoma.

Entire report and diagnosis completed by:

-----END OF REPORT-----

Criteria	W 4/11/13	Yes	No

Source: NCI Genomic Data Commons file a52ff414-2536-4477-81d3-0af2d4606105 (TCGA-CV-A6JE.2A9E86E4-97B2-4E8F-8FF4-FC31707A35C9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).